Gene-level copy-number profile of tumor specimen TCGA-OR-A5K9-01A from TCGA case TCGA-OR-A5K9, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 61.9 years (22,596 days).
Specimen TCGA-OR-A5K9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.3d18122c-81d2-4112-8250-3d2f04896a63.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5K9-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e403dd21-8f3a-41f9-a0dd-f5ac9289864e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 968; copy number 2: 20,423; copy number 3: 20,121; copy number 4: 9,085; copy number 5: 7,856; copy number 6: 410; copy number 7: 516; copy number 8: 189; copy number 10: 85; copy number 11: 136; copy number 12: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5K9-01A-11D-A29H-01): tumor purity 0.94, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,932,238, 3 genes (within-gene range 0–1): MIR4447, AC069504.1, LINC00901.
- chr3:117,026,698–117,027,039, 1 gene: PTMAP8.
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.
- chr22:28,772,674–28,848,559, 5 genes (within-gene range 0–1): CCDC117, XBP1, Z93930.2, Z93930.3, Z93930.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 944 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–667,168, 25 genes, copy number 10 (within-gene range 6–10): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72.
- chr5:32,888,236–33,298,066, 1 gene, copy number 7 (within-gene range 2–7): AC010343.3.
- chr5:33,008,934–33,522,230, 10 genes, copy number 7 (within-gene range 2–7): AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1.
- chr5:34,651,457–35,230,487, 13 genes, copy number 7 (within-gene range 5–7): AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1.
- chr5:35,678,484–38,685,126, 60 genes, copy number 7 (within-gene range 5–7): AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1.
- chr5:41,730,065–42,729,519, 14 genes, copy number 8: OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1.
- chr12:56,162,359–59,812,576, 136 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr12:64,696,191–65,966,291, 28 genes, copy number 7–12 (within-gene range 4–12): AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1.
- chr19:94,062–2,740,048, 175 genes, copy number 8 (broad region; genes not listed).
- chr19:3,538,261–3,574,290, 1 gene, copy number 7 (within-gene range 4–7): MFSD12.
- chr19:3,544,199–4,670,362, 68 genes, copy number 7 (broad region; genes not listed).
- chr19:9,959,561–17,026,815, 412 genes, copy number 7–10 (broad region; genes not listed).
- chr19:17,051,994–17,055,087, 1 gene, copy number 7: AC020908.1.

Autosomal genes at a single copy (total copy number 1): 968. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
